Somatic mutation profile of tumor specimen 0E0A05 from CCDI case PBCUDB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E0A05: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3380a6d-230d-4006-8af1-e09af3e8e8cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZHVL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36c593a3-ac79-4dc0-9543-61913da41cd2

The open-access MAF lists 19 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 5, Nonsense Mutation 2, Intron 2, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.832C>T p.R278* (on ENST00000281708 / NM_001349798.2; = p.R198* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 177/636 reads (28%) | hotspot (GDC flag); catalogued as COSV55891638; called by muse, mutect2, varscan2
- CDR2 | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 52/1155 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.215); catalogued as rs147836696; called by muse, mutect2
- CHD7 | c.6775+1G>T p.X2259_splice | Splice Site (SNP) | VAF 154/413 reads (37%) | catalogued as CS109314; called by muse, mutect2, varscan2
- DNAH5 | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 48/998 reads (5%) | catalogued as rs1314223921, CM065118, COSV54247530; called by muse, mutect2
- FLRT2 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 217/532 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs540955201, COSV58135756; called by muse, mutect2, varscan2
- VEGFC | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 40/733 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776655496, COSV54593811; called by muse, mutect2
- ADGRG2 | c.1394T>G p.F465C (on ENST00000379869 / NM_001079858.3; = p.F462C on NM_005756.4) | Missense Mutation (SNP) | VAF 24/600 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CNTRL | c.6838C>A p.Q2280K | Missense Mutation (SNP) | VAF 38/1122 reads (3%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.952); called by muse, mutect2
- HELZ | c.2153G>C p.G718A | Missense Mutation (SNP) | VAF 54/901 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2
- OTULINL | c.746A>G p.Y249C | Missense Mutation (SNP) | VAF 66/1094 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.939); called by muse, mutect2
- TXLNA | c.1037A>T p.E346V | Missense Mutation (SNP) | VAF 96/1192 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.213); called by muse, mutect2
- ESPN | c.1326G>A p.P442= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as rs779665303; called by muse, mutect2, varscan2
- FAM189A1 | c.774G>A p.P258= | Silent (SNP) | VAF 44/930 reads (5%) | catalogued as rs1046300306, COSV99722840; called by muse, mutect2
- FBXL12 | c.480C>T p.R160= | Silent (SNP) | VAF 23/404 reads (6%) | catalogued as rs973637574, COSV99928021; called by muse, mutect2
- UGT2B4 | c.1008G>T p.L336= | Silent (SNP) | VAF 20/669 reads (3%) | catalogued as COSV59318392, COSV59321335; called by muse, mutect2
- ZSCAN10 | c.2022C>T p.C674= (on ENST00000252463; = p.C729= on NM_032805.3) | Silent (SNP) | VAF 34/193 reads (18%) | called by muse, mutect2, varscan2
- ABHD17A | c.528-29C>T | Intron (SNP) | VAF 66/843 reads (8%) | catalogued as rs142480031; called by muse, mutect2
- C22orf42 | c.-85C>T | 5'UTR (SNP) | VAF 17/48 reads (35%) | catalogued as rs186813867; called by muse, mutect2, varscan2
- LTBR | c.319+27dup | Intron (INS) | VAF 42/358 reads (12%) | catalogued as rs563848590; called by mutect2, varscan2
